Somatic mutation profile of tumor specimen 0DFSSZ from CCDI case PBBRWM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 13.9 years (5,086 days).
Specimen 0DFSSZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 386179e9-7994-401b-94b8-78eb0622c6d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFSS2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f64697a4-ea4c-4685-8bad-5604caddcd48

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD14A-ACY1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 327/794 reads (41%) | SIFT deleterious, low confidence (0); catalogued as rs746216035, COSV56472091; called by muse, mutect2, varscan2
- KEL | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 62/988 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.498); catalogued as rs61729042, CM015251, COSV62333782; called by muse, mutect2
- PTPRR | c.852G>C p.K284N | Missense Mutation (SNP) | VAF 42/1119 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99316576; called by muse, mutect2
- ZFAT | c.1288T>A p.W430R | Missense Mutation (SNP) | VAF 176/490 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100914468; called by muse, mutect2
- A4GNT | c.586G>T p.G196W | Missense Mutation (SNP) | VAF 244/631 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- BPIFC | c.1218-1G>T p.X406_splice | Splice Site (SNP) | VAF 215/542 reads (40%) | called by muse, mutect2, varscan2
- CBLB | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 31/985 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- TXNDC11 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 157/364 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); called by muse, varscan2
- USP39 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 38/1334 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC5AC | c.12216G>A p.G4072= | Silent (SNP) | VAF 23/587 reads (4%) | catalogued as rs1202882967; called by muse, mutect2
- TECPR2 | c.2910G>A p.E970= | Silent (SNP) | VAF 196/496 reads (40%) | called by muse, mutect2, varscan2
